Somatic mutation profile of tumor specimen TCGA-D1-A17U-01A (aliquot TCGA-D1-A17U-01A-21D-A12J-09) from TCGA case TCGA-D1-A17U, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Tumor grade: G2; Age at diagnosis: 53.5 years (19,544 days).
Specimen TCGA-D1-A17U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 700c7676-be1e-406c-923b-6d9932f11b55.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A17U-10A (Blood Derived Normal), aliquot TCGA-D1-A17U-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41483274-8373-48c5-82c9-f2a6413dba23

The open-access MAF lists 490 somatic variants for this specimen: 377 protein-altering or splice-affecting, 104 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 232, Silent 104, Frame Shift Del 92, Nonsense Mutation 23, Frame Shift Ins 15, Splice Site 10, In Frame Del 4, 5'UTR 2, Intron 2, RNA 2, 3'Flank 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALG6 | c.634dup p.C212Lfs*9 | Frame Shift Ins (INS) | VAF 44/290 reads (15%) | catalogued as rs879133727; ClinVar: likely pathogenic; called by mutect2, varscan2
- BRCA1 | c.1961del p.K654Sfs*47 | Frame Shift Del (DEL) | VAF 85/281 reads (30%) | catalogued as rs80357522, CD076746, CD951610; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by mutect2, varscan2
- COL5A1 | c.2897del p.P966Lfs*108 | Frame Shift Del (DEL) | VAF 40/151 reads (26%) | catalogued as rs1179967153; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KCNH2 | c.1193G>A p.W398* | Nonsense Mutation (SNP) | VAF 43/112 reads (38%) | catalogued as rs794728366, CM097339, COSV51139889; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 268/482 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LRPPRC | c.3147del p.A1051Hfs*6 | Frame Shift Del (DEL) | VAF 141/392 reads (36%) | catalogued as rs769022521; ClinVar: pathogenic; called by mutect2, varscan2
- MYH11 | c.5787-4707dup | Intron (INS) | VAF 16/72 reads (22%) | catalogued as rs747392139; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- NFE2L2 | c.239C>G p.T80R | Missense Mutation (SNP) | VAF 174/486 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67960012, COSV67960020, COSV67960088; called by muse, mutect2, varscan2
- PCARE | c.2298del p.R767Dfs*30 | Frame Shift Del (DEL) | VAF 19/58 reads (33%) | catalogued as rs1553354660; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- PMP22 | c.433del p.L145Wfs*10 | Frame Shift Del (DEL) | VAF 10/75 reads (13%) | catalogued as rs1567698872; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTCH1 | c.3191C>T p.T1064M | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs368417828, CM164222; ClinVar: likely benign / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.634+1G>T p.X212_splice | Splice Site (SNP) | VAF 61/164 reads (37%) | hotspot (GDC flag); catalogued as CS110219, CS1314438, COSV64295775, COSV64297457, COSV64302278; called by muse, varscan2*
- SCN4A | c.2023C>T p.R675W | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs121908556, CM043573, CM043574, COSV71127096; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TCF4 | c.1864C>T p.R622* | Nonsense Mutation (SNP) | VAF 5/44 reads (11%) | catalogued as rs1131691735, CM120290, COSV61897774; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.216del p.V73Wfs*50 | Frame Shift Del (DEL) | VAF 18/69 reads (26%) | catalogued as rs730882018; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- AATF | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 89/275 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.139); catalogued as rs115334426; called by muse, mutect2, varscan2
- ABCA5 | c.911del p.F304Sfs*12 | Frame Shift Del (DEL) | VAF 21/84 reads (25%) | catalogued as rs776887626; called by mutect2, pindel, varscan2
- ABCA7 | c.1547G>A p.R516H | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs377020137; called by muse, mutect2, varscan2
- ABCC5 | c.3437C>T p.T1146M | Missense Mutation (SNP) | VAF 31/274 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); catalogued as rs759305243, COSV55590846; called by muse, mutect2
- ACTRT1 | c.739C>T p.H247Y | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as rs1272565964, COSV64419512; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 90/242 reads (37%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMDEC1 | c.1022del p.K341Rfs*7 | Frame Shift Del (DEL) | VAF 52/124 reads (42%) | catalogued as rs746174250; called by mutect2, varscan2
- ADAMTS2 | c.2614G>A p.G872R | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs779277427, COSV52373409; called by muse, mutect2, varscan2
- ADARB1 | c.1291C>T p.R431* | Nonsense Mutation (SNP) | VAF 61/196 reads (31%) | catalogued as COSV62344243; called by muse, mutect2, varscan2
- ADD2 | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781842295, COSV52458987; called by muse, mutect2, varscan2
- ADRA2A | c.1225T>C p.Y409H | Missense Mutation (SNP) | VAF 77/230 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54528213; called by muse, mutect2, varscan2
- AICDA | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.821); catalogued as COSV57564653; called by muse, mutect2, varscan2
- AIFM3 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.006); catalogued as rs1441375131, COSV58999216; called by muse, mutect2, varscan2
- AKAP11 | c.4913C>A p.P1638H | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50297325; called by muse, mutect2, varscan2
- ALDH1B1 | c.1504T>C p.Y502H | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66619828; called by muse, mutect2, varscan2
- AMER2 | c.1484G>A p.R495Q | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.083); catalogued as COSV63437497; called by muse, mutect2, varscan2
- ANGPTL2 | c.863C>T p.T288I | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.081); catalogued as COSV52222961; called by muse, mutect2, varscan2
- ANGPTL7 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs757936149, COSV63872163; called by muse, mutect2, varscan2
- ANXA5 | c.353C>T p.T118I | Missense Mutation (SNP) | VAF 34/525 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1388549118, COSV56639125; called by muse, mutect2
- AP2B1 | c.1564C>T p.R522W | Missense Mutation (SNP) | VAF 115/331 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51999922; called by muse, mutect2, varscan2
- AP3B1 | c.2248A>G p.S750G | Missense Mutation (SNP) | VAF 96/302 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV54884698; called by muse, mutect2, varscan2
- APEX2 | c.154A>T p.T52S | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.71); catalogued as COSV66624037; called by muse, mutect2, varscan2
- ARHGAP30 | c.1529_1531del p.F510del | In Frame Del (DEL) | VAF 22/71 reads (31%) | catalogued as rs778286823; called by mutect2, pindel, varscan2
- ARHGEF10L | c.2491G>A p.G831R | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as rs1013769138, COSV51433455; called by muse, mutect2, varscan2
- ARID2 | c.853C>T p.R285W | Missense Mutation (SNP) | VAF 138/434 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57596894; called by mutect2, varscan2
- ARRDC3 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); catalogued as rs1372725760, COSV54365359; called by muse, mutect2, varscan2
- ASAP3 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 51/171 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs372166776; called by muse, mutect2, varscan2
- ASB2 | c.1204C>T p.R402C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60112110; called by muse, varscan2
- ATAD5 | c.2188C>T p.R730C | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778157984, COSV58974045, COSV58975112; called by muse, mutect2, varscan2
- ATR | c.2320del p.I774Yfs*5 | Frame Shift Del (DEL) | VAF 54/143 reads (38%) | catalogued as rs757500301, CD112378; ClinVar: not provided; called by mutect2, varscan2
- ATXN2L | c.2997del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 7/13 reads (54%) | catalogued as rs1288664341; called by mutect2, varscan2
- AUH | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs773055968, COSV57863545; called by muse, mutect2, varscan2
- BICRA | c.2810del p.P937Hfs*10 | Frame Shift Del (DEL) | VAF 12/26 reads (46%) | catalogued as rs755506199; called by mutect2, varscan2
- BIRC6 | c.7604C>A p.P2535H | Missense Mutation (SNP) | VAF 36/452 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV70199842; called by muse, mutect2
- BMP15 | c.131T>C p.L44P | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV53140660; called by muse, mutect2
- BSN | c.660T>A p.C220* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as COSV56519200; called by muse, mutect2
- C15orf39 | c.1124C>T p.T375I | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); catalogued as rs746853077, COSV62296925; called by muse, mutect2, varscan2
- C5orf24 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV57542656; called by muse, mutect2, varscan2
- CALR3 | c.805G>T p.G269C | Missense Mutation (SNP) | VAF 83/263 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV54170004; called by muse, mutect2, varscan2
- CARMIL2 | c.3377G>A p.R1126Q | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs756446842, COSV54667968; called by muse, mutect2, varscan2
- CASP2 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 62/190 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as rs769956463, COSV60081895; called by muse, mutect2, varscan2
- CASP5 | c.400C>T p.L134F | Missense Mutation (SNP) | VAF 157/411 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as rs886487219, COSV52828945; called by muse, mutect2, varscan2
- CBLL1 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 34/342 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as COSV56029048; called by muse, mutect2
- CCDC39 | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 99/296 reads (33%) | catalogued as COSV56485118; called by muse, mutect2, varscan2
- CCDC50 | c.83C>T p.T28I | Missense Mutation (SNP) | VAF 19/688 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV66668293; called by muse, mutect2
- CCDC50 | c.1242+2T>C p.X414_splice (on ENST00000392455 / NM_178335.3; = p.X238_splice on NM_174908.4) | Splice Site (SNP) | VAF 22/316 reads (7%) | catalogued as rs1340255111, COSV66668296; called by muse, mutect2
- CDC42BPG | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV61347571; called by muse, mutect2
- CDC73 | c.687_688dup p.V230Efs*28 | Frame Shift Ins (INS) | VAF 81/244 reads (33%) | catalogued as rs760591174; called by mutect2, varscan2
- CDK12 | c.637G>A p.V213M | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.121); catalogued as COSV71000864; called by muse, mutect2
- CELSR2 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.267); catalogued as COSV54772862; called by muse, mutect2, varscan2
- CFH | c.2706G>T p.E902D | Missense Mutation (SNP) | VAF 71/214 reads (33%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); catalogued as COSV66409057; called by muse, mutect2, varscan2
- CLINT1 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 58/836 reads (7%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.627); catalogued as COSV51624616; called by muse, mutect2
- CLSTN2 | c.1721A>G p.D574G | Missense Mutation (SNP) | VAF 21/301 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV71721151; called by muse, mutect2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 24/61 reads (39%) | catalogued as rs374805044; called by mutect2, varscan2
- COL25A1 | c.1127G>T p.G376V | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67650917; called by muse, mutect2
- COL4A6 | c.2398C>T p.R800W | Missense Mutation (SNP) | VAF 57/184 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.108); catalogued as rs1479175908, COSV57867800; called by muse, mutect2, varscan2
- CRNKL1 | c.2117C>T p.T706M | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1318168101, COSV58548575; called by muse, mutect2
- CSDE1 | c.2375G>A p.R792H (on ENST00000358528 / NM_001007553.3; = p.R761H on NM_007158.6) | Missense Mutation (SNP) | VAF 85/290 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.198); catalogued as rs375339756; called by muse, mutect2, varscan2
- CTCF | c.1810del p.S604Lfs*27 | Frame Shift Del (DEL) | VAF 125/410 reads (30%) | catalogued as COSV50470772; called by mutect2, pindel, varscan2
- CTSH | c.179G>A p.S60N | Missense Mutation (SNP) | VAF 40/492 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV54985206; called by muse, mutect2
- CUL4B | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 114/271 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.121); catalogued as rs1172227126, COSV60687808; called by muse, mutect2, varscan2
- CYP11B2 | c.1284G>A p.W428* | Nonsense Mutation (SNP) | VAF 39/117 reads (33%) | catalogued as COSV59996115; called by muse, mutect2, varscan2
- DAB2IP | c.2047C>T p.Q683* (on ENST00000408936; = p.Q655* on NM_032552.3) | Nonsense Mutation (SNP) | VAF 29/61 reads (48%) | catalogued as COSV52260591; called by muse, mutect2, varscan2
- DCC | c.2098A>G p.T700A | Missense Mutation (SNP) | VAF 98/259 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59105395; called by muse, mutect2, varscan2
- DDX3X | c.1066T>C p.F356L (on ENST00000399959; = p.F357L on NM_001356.5) | Missense Mutation (SNP) | VAF 24/440 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV67863677, COSV67864841; called by muse, mutect2
- DENND2A | c.2858A>G p.Q953R | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV52052137; called by muse, mutect2, varscan2
- DENND3 | c.2722G>A p.E908K | Missense Mutation (SNP) | VAF 66/188 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs1001301736, COSV52802817; called by muse, mutect2, varscan2
- DHX34 | c.2812C>T p.R938* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as rs146308675; called by muse, mutect2, varscan2
- DISP3 | c.2120G>A p.G707D | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.286); catalogued as COSV53828480; called by muse, mutect2, varscan2
- DISP3 | c.3701G>T p.G1234V | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53828492; called by muse, mutect2, varscan2
- DLEC1 | c.3260G>T p.S1087I | Missense Mutation (SNP) | VAF 56/187 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV57300436; called by muse, mutect2, varscan2
- DLG5 | c.4442del p.P1481Qfs*88 | Frame Shift Del (DEL) | VAF 24/93 reads (26%) | catalogued as rs778796396, CM066561; called by mutect2, pindel, varscan2
- DLG5 | c.2198G>C p.S733T | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.497); catalogued as COSV64948257; called by muse, mutect2, varscan2
- DNAH10 | c.6163G>A p.E2055K (on ENST00000409039; = p.E1994K on NM_207437.3) | Missense Mutation (SNP) | VAF 85/199 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV68994631; called by muse, mutect2, varscan2
- DNAH11 | c.10967G>A p.R3656H | Missense Mutation (SNP) | VAF 98/283 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as rs765797284, COSV60958091; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 37/239 reads (15%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DPEP3 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754473743, COSV52050917; called by muse, mutect2
- DPP9 | c.1846C>T p.R616C (on ENST00000598800; = p.R645C on NM_139159.5) | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.39); catalogued as rs772251728, COSV53591574; called by muse, mutect2, varscan2
- DPP9 | c.820C>T p.R274* (on ENST00000598800; = p.R303* on NM_139159.5) | Nonsense Mutation (SNP) | VAF 10/142 reads (7%) | catalogued as COSV53591584; called by muse, mutect2
- DUSP10 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs770902966, COSV60457740, COSV60458110; called by muse, mutect2, varscan2
- DYNC1I2 | c.105del p.E36Kfs*34 | Frame Shift Del (DEL) | VAF 32/80 reads (40%) | catalogued as rs755197346; called by mutect2, varscan2
- EDC3 | c.1361A>G p.D454G | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as COSV59340509; called by muse, mutect2, varscan2
- EFL1 | c.1984G>A p.A662T | Missense Mutation (SNP) | VAF 47/347 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV51605999; called by muse, mutect2, varscan2
- EIF3K | c.344A>G p.Q115R | Missense Mutation (SNP) | VAF 60/201 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as COSV50264137; called by muse, mutect2, varscan2
- ETAA1 | c.2610A>C p.Q870H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV55473191; called by muse, mutect2
- F2R | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1370045691, COSV59929223; called by muse, mutect2, varscan2
- FABP9 | c.156A>G p.I52M | Missense Mutation (SNP) | VAF 130/408 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as COSV66911594; called by muse, mutect2, varscan2
- FAM118A | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 29/81 reads (36%) | catalogued as COSV53417451; called by muse, mutect2, varscan2
- FAT4 | c.12509G>A p.R4170H | Missense Mutation (SNP) | VAF 60/186 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs758666028, COSV58688122; called by muse, mutect2, varscan2
- FKBP4 | c.770A>G p.E257G | Missense Mutation (SNP) | VAF 52/206 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV50009199; called by muse, mutect2, varscan2
- FLCN | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs749770193, COSV53259704; ClinVar: uncertain significance; called by muse, varscan2
- FTHL17 | c.543A>T p.K181N | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.127); catalogued as COSV63267029; called by muse, mutect2, varscan2
- FUT8 | c.1547G>A p.R516Q (on ENST00000360689 / NM_001371534.1; = p.R353Q on NM_004480.4) | Missense Mutation (SNP) | VAF 103/287 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs745805077, COSV61280665; called by muse, mutect2, varscan2
- FUZ | c.1169T>G p.L390R | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1226811597, COSV58241812; called by muse, mutect2
- FYB1 | c.972dup p.P325Afs*43 | Frame Shift Ins (INS) | VAF 74/246 reads (30%) | catalogued as rs748874978; called by mutect2, varscan2
- GABRA6 | c.1311G>T p.W437C | Missense Mutation (SNP) | VAF 12/268 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50882370, COSV50892323; called by muse, mutect2
- GCNT1 | c.628T>G p.W210G | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65057837; called by muse, mutect2, varscan2
- GGCT | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 145/401 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as rs766416927, COSV50040884; called by muse, mutect2, varscan2
- GJA5 | c.930A>T p.E310D | Missense Mutation (SNP) | VAF 136/375 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV54784508, COSV99605672; called by muse, mutect2, varscan2
- GK | c.1598T>C p.F533S (on ENST00000427190 / NM_001205019.2; = p.F527S on NM_001128127.2) | Missense Mutation (SNP) | VAF 17/533 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.209); catalogued as COSV100970775; called by muse, mutect2
- GLDC | c.3031C>T p.P1011S | Missense Mutation (SNP) | VAF 134/358 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.473); catalogued as COSV58679224, COSV58680554; called by muse, mutect2, varscan2
- GOLGA4 | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.058); catalogued as COSV62710995; called by muse, mutect2, varscan2
- GPR174 | c.947C>A p.A316E | Missense Mutation (SNP) | VAF 61/187 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV52132690; called by muse, mutect2, varscan2
- GRB10 | c.1265C>T p.T422M (on ENST00000398812; = p.T376M on NM_001001549.3) | Missense Mutation (SNP) | VAF 14/193 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs932870989, COSV60010417; called by muse, mutect2
- GRM5 | c.3193G>A p.V1065I (on ENST00000305447 / NM_001143831.2; = p.V1033I on NM_000842.4) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.385); catalogued as COSV59607046; called by muse, mutect2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 20/58 reads (34%) | catalogued as rs754199513; called by mutect2, varscan2
- HDC | c.1612A>T p.N538Y | Missense Mutation (SNP) | VAF 73/226 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.054); catalogued as COSV51071080; called by muse, mutect2, varscan2
- HEATR1 | c.2345C>T p.A782V | Missense Mutation (SNP) | VAF 72/198 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV63981392; called by muse, mutect2, varscan2
- HECTD1 | c.5037G>T p.E1679D | Missense Mutation (SNP) | VAF 50/450 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV67946563; called by muse, mutect2, varscan2
- HECTD4 | c.8824G>T p.D2942Y | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV66392801; called by muse, mutect2, varscan2
- HGSNAT | c.133del p.R45Dfs*5 | Frame Shift Del (DEL) | VAF 78/218 reads (36%) | catalogued as rs1220771600; called by mutect2, pindel, varscan2
- HIVEP3 | c.2312C>T p.T771M | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs762556103, COSV56016216; called by muse, mutect2, varscan2
- HMG20B | c.461_463del p.K154del | In Frame Del (DEL) | VAF 54/218 reads (25%) | catalogued as rs767799999; called by pindel, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 46/117 reads (39%) | catalogued as rs761272507; called by mutect2, varscan2
- HNF4A | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 6/137 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.773); catalogued as rs1385303123, COSV57383633; called by muse, mutect2
- HOMEZ | c.1324A>G p.T442A | Missense Mutation (SNP) | VAF 187/602 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV62537130; called by muse, mutect2, varscan2
- IGHD | c.494C>T p.T165I | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.976); catalogued as COSV66655174; called by muse, mutect2, varscan2
- IGSF9 | c.1420C>T p.R474* (on ENST00000368094 / NM_001135050.2; = p.R458* on NM_020789.4) | Nonsense Mutation (SNP) | VAF 18/47 reads (38%) | catalogued as rs569197292, COSV63639710; called by muse, mutect2, varscan2
- INPPL1 | c.2401C>T p.R801C | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs144781166; called by muse, mutect2, varscan2
- INTS12 | c.850T>A p.S284T | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.696); catalogued as COSV60862436; called by muse, mutect2, varscan2
- INTS9 | c.1165C>T p.Q389* | Nonsense Mutation (SNP) | VAF 61/180 reads (34%) | catalogued as COSV68434285; called by muse, mutect2, varscan2
- JAK1 | c.2795T>G p.L932R | Missense Mutation (SNP) | VAF 179/537 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61091638; called by muse, mutect2, varscan2
- JAK2 | c.2682C>G p.D894E | Missense Mutation (SNP) | VAF 95/279 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as COSV67614469; called by muse, mutect2, varscan2
- KCNA1 | c.1134G>A p.M378I | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as COSV66837485; called by muse, mutect2, varscan2
- KCNH4 | c.642del p.S215Lfs*62 | Frame Shift Del (DEL) | VAF 35/119 reads (29%) | catalogued as COSV99236896; called by mutect2, pindel, varscan2
- KCNJ6 | c.747G>T p.E249D | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV55709563, COSV55714990; called by muse, mutect2, varscan2
- KCNQ1 | c.1377C>A p.D459E | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.019); catalogued as COSV50110696; called by muse, mutect2, varscan2
- KIAA0930 | c.359C>T p.A120V (on ENST00000336156 / NM_001009880.2; = p.A125V on NM_015264.2) | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1163738570, COSV52663464; called by muse, mutect2, varscan2
- KIAA1522 | c.662C>T p.A221V (on ENST00000373480 / NM_001198972.2; = p.A280V on NM_020888.3) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs754022301, COSV53864840; called by muse, mutect2, varscan2
- KLHL13 | c.1263G>C p.W421C | Missense Mutation (SNP) | VAF 90/245 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53248511; called by muse, mutect2, varscan2
- KRT38 | c.1265C>T p.T422M | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as rs146369884; called by muse, mutect2, varscan2
- LACTB2 | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 30/87 reads (34%) | catalogued as rs867731670, COSV52567552; called by muse, mutect2, varscan2
- LGALS9B | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 108/300 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as rs561766300, COSV60865232; called by muse, mutect2, varscan2
- LHX9 | c.221G>A p.C74Y | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61329015; called by muse, mutect2, varscan2
- LPA | c.3120del p.F1040Lfs*5 | Frame Shift Del (DEL) | VAF 30/155 reads (19%) | catalogued as rs753812356; called by mutect2, pindel, varscan2
- LRRC36 | c.487del p.S163Afs*7 | Frame Shift Del (DEL) | VAF 48/160 reads (30%) | catalogued as COSV99338780; called by mutect2, pindel, varscan2
- LYST | c.10411del p.E3471Nfs*44 | Frame Shift Del (DEL) | VAF 50/146 reads (34%) | catalogued as COSV67706498; called by mutect2, pindel, varscan2
- MAGI3 | c.2747A>G p.H916R | Missense Mutation (SNP) | VAF 80/241 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1308385671, COSV56836544; called by muse, mutect2, varscan2
- MAP3K10 | c.1264C>T p.R422W | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776214953, COSV53422737; called by muse, mutect2, varscan2
- MAP4K4 | c.418G>T p.G140* | Nonsense Mutation (SNP) | VAF 14/418 reads (3%) | catalogued as COSV56332088; called by muse, mutect2
- MAPKBP1 | c.573C>G p.Y191* | Nonsense Mutation (SNP) | VAF 39/142 reads (27%) | catalogued as COSV52962228; called by muse, mutect2, varscan2
- MARCHF8 | c.218C>T p.T73M | Missense Mutation (SNP) | VAF 65/195 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.799); catalogued as rs777790919, COSV60571588; called by muse, mutect2, varscan2
- MBD6 | c.2200del p.Q734Nfs*18 | Frame Shift Del (DEL) | VAF 24/71 reads (34%) | catalogued as rs749738168; called by mutect2, pindel, varscan2
- MED25 | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200785685; called by muse, mutect2, varscan2
- METTL25 | c.82A>G p.R28G | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV50259290; called by muse, mutect2
- MFSD6 | c.274T>C p.Y92H | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55622979; called by muse, mutect2, varscan2
- MICU2 | c.358+1G>A p.X120_splice | Splice Site (SNP) | VAF 42/134 reads (31%) | catalogued as rs370202488, COSV66674271; called by muse, mutect2, varscan2
- MKS1 | c.115C>A p.L39I | Missense Mutation (SNP) | VAF 60/237 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.063); catalogued as COSV58304319; called by muse, mutect2, varscan2
- MLH3 | c.130A>G p.R44G | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53135141; called by muse, mutect2, varscan2
- MPHOSPH10 | c.545A>G p.Q182R | Missense Mutation (SNP) | VAF 95/263 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV54906080; called by muse, mutect2, varscan2
- MPP1 | c.865G>A p.G289R | Missense Mutation (SNP) | VAF 94/278 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65729640; called by muse, mutect2, varscan2
- MPZL2 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 14/287 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV54048921; called by muse, mutect2
- MRGBP | c.600G>T p.K200N | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV65111477, COSV65111737; called by muse, varscan2
- MRPL46 | c.369G>A p.M123I | Missense Mutation (SNP) | VAF 78/279 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV56900105; called by muse, mutect2, varscan2
- MTUS2 | c.3083C>T p.A1028V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.91); PolyPhen benign (0.044); catalogued as COSV70917069; called by muse, mutect2, varscan2
- MUL1 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.433); catalogued as COSV51641948; called by muse, mutect2, varscan2
- MYBL2 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs772918018, COSV53830285; called by muse, mutect2
- MYH6 | c.2398C>T p.R800C | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs763477425, COSV62451051; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO16 | c.2525del p.F842Sfs*17 | Frame Shift Del (DEL) | VAF 34/112 reads (30%) | catalogued as rs761471964; called by mutect2, varscan2
- MYO1A | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 38/255 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.658); catalogued as COSV55654401; called by muse, mutect2, varscan2
- MYO1D | c.136G>A p.V46I | Missense Mutation (SNP) | VAF 63/175 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.791); catalogued as rs764719897, COSV59013998; called by muse, mutect2, varscan2
- MYO1G | c.2324C>T p.P775L | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs745961199, COSV51854913; called by muse, mutect2, varscan2
- MYO5A | c.4123A>G p.K1375E | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as COSV62560717; called by muse, mutect2, varscan2
- MYO5B | c.1546-2A>G p.X516_splice | Splice Site (SNP) | VAF 70/210 reads (33%) | catalogued as COSV53220021; called by muse, mutect2, varscan2
- MYOM2 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as rs147661043, COSV50717399; called by muse, mutect2, varscan2
- N4BP2 | c.4949del p.N1650Mfs*17 | Frame Shift Del (DEL) | VAF 41/190 reads (22%) | catalogued as rs763929397; called by mutect2, varscan2
- NAT10 | c.25C>T p.R9* | Nonsense Mutation (SNP) | VAF 91/251 reads (36%) | catalogued as rs756936856, COSV57664089; called by muse, mutect2, varscan2
- NCAPD3 | c.2725dup p.Q909Pfs*12 | Frame Shift Ins (INS) | VAF 54/208 reads (26%) | catalogued as rs770284236; called by mutect2, varscan2
- NEPRO | c.75del p.V26* | Frame Shift Del (DEL) | VAF 5/18 reads (28%) | catalogued as COSV58723480; called by mutect2, varscan2
- NIBAN3 | c.1527del p.R510Afs*3 | Frame Shift Del (DEL) | VAF 23/95 reads (24%) | catalogued as rs1568458771; called by mutect2, pindel, varscan2
- NIPA2 | c.98del p.K33Rfs*12 | Frame Shift Del (DEL) | VAF 108/272 reads (40%) | catalogued as rs145147241; called by mutect2, varscan2
- NIPBL | c.7098G>T p.Q2366H | Missense Mutation (SNP) | VAF 66/155 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV56952589; called by muse, mutect2, varscan2
- NLRP4 | c.796A>G p.R266G | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.267); catalogued as COSV56714920; called by muse, mutect2, varscan2
- NODAL | c.919C>T p.R307* | Nonsense Mutation (SNP) | VAF 30/430 reads (7%) | catalogued as rs949415691, COSV54661563; called by muse, mutect2
- NPC1L1 | c.1004C>T p.T335I | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs772019231, COSV56925770; called by muse, mutect2, varscan2
- NYAP2 | c.352T>C p.S118P | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56006328; called by muse, mutect2, varscan2
- OIT3 | c.494G>A p.C165Y | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1215770147, COSV61826253; called by muse, mutect2, varscan2
- OPRK1 | c.515C>A p.P172H | Missense Mutation (SNP) | VAF 71/208 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55570913; called by muse, mutect2, varscan2
- OR2Z1 | c.943T>C p.*315Rext*7 | Nonstop Mutation (SNP) | VAF 38/101 reads (38%) | catalogued as rs1208345822, COSV60692565; called by muse, mutect2, varscan2
- OR51S1 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 51/308 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs757816643, COSV59058583; called by muse, mutect2, varscan2
- OR51V1 | c.770C>A p.P257H | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58315278; called by muse, mutect2
- P4HB | c.1160del p.N387Tfs*118 | Frame Shift Del (DEL) | VAF 46/152 reads (30%) | catalogued as rs763394045; called by mutect2, varscan2
- PALM | c.127C>T p.Q43* | Nonsense Mutation (SNP) | VAF 19/41 reads (46%) | catalogued as COSV52768470; called by muse, mutect2, varscan2
- PAPPA | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as rs199822574, COSV60284182, COSV60284455; called by muse, mutect2, varscan2
- PATZ1 | c.343G>T p.G115W | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.982); catalogued as COSV53229618; called by muse, mutect2, varscan2
- PCDHB3 | c.903G>A p.M301I | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV50577543; called by muse, mutect2, varscan2
- PCDHGA1 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 72/172 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.477); catalogued as COSV65296356; called by muse, mutect2, varscan2
- PCNT | c.9106del p.M3036Wfs*14 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | catalogued as rs1268347124; called by mutect2, pindel, varscan2
- PHACTR3 | c.311G>A p.G104D | Missense Mutation (SNP) | VAF 10/349 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.371); catalogued as COSV63028596; called by muse, mutect2
- PI4KA | c.2236C>T p.R746* | Nonsense Mutation (SNP) | VAF 10/153 reads (7%) | catalogued as rs1202099178, COSV55412213; called by muse, mutect2
- PIAS3 | c.1259C>T p.P420L | Missense Mutation (SNP) | VAF 80/244 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs369391516; called by muse, mutect2, varscan2
- PIK3R1 | c.1728del p.R577Efs*5 (on ENST00000521381 / NM_181523.3; = p.R307Efs*5 on NM_181504.4) | Frame Shift Del (DEL) | VAF 120/369 reads (33%) | catalogued as COSV57131154; called by mutect2, pindel, varscan2
- PITPNM1 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs201959831, COSV62708361; called by muse, mutect2, varscan2
- PIWIL1 | c.1621T>C p.Y541H | Missense Mutation (SNP) | VAF 121/356 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV55347278; called by muse, mutect2, varscan2
- PLXNA3 | c.2447T>G p.L816R | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV63754247; called by muse, mutect2, varscan2
- PON2 | c.195del p.F65Lfs*5 | Frame Shift Del (DEL) | VAF 106/391 reads (27%) | catalogued as rs1201102139; called by mutect2, pindel, varscan2
- PPP2R5A | c.*7del | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | catalogued as rs540232176; called by mutect2, varscan2
- PPP2R5B | c.565T>C p.Y189H | Missense Mutation (SNP) | VAF 185/491 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV51210430; called by muse, mutect2, varscan2
- PRPF8 | c.5165G>A p.S1722N | Missense Mutation (SNP) | VAF 71/230 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV59263735; called by muse, mutect2, varscan2
- PRR12 | c.2587G>A p.V863I (on ENST00000615927; = p.V1684I on NM_020719.3) | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs528148742, COSV69817840; called by muse, mutect2, varscan2
- PSME3IP1 | c.386A>G p.K129R | Missense Mutation (SNP) | VAF 128/375 reads (34%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.757); catalogued as rs761482807, COSV58429358; called by muse, mutect2, varscan2
- PSTPIP1 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs781549267, COSV51200641; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRM | c.86T>C p.F29S | Missense Mutation (SNP) | VAF 21/305 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59861527; called by muse, mutect2
- PTPRO | c.3616A>G p.S1206G (on ENST00000281171 / NM_030667.3; = p.S1178G on NM_002848.4) | Missense Mutation (SNP) | VAF 20/389 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.932); catalogued as COSV55511409; called by muse, mutect2
- RAB13 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 72/244 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.452); catalogued as COSV63933762; called by muse, mutect2, varscan2
- RAB20 | c.560G>A p.G187D | Missense Mutation (SNP) | VAF 87/261 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1353258333, COSV57440764; called by muse, mutect2, varscan2
- RAB7A | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54041936; called by muse, mutect2, varscan2
- RDH13 | c.799G>A p.A267T (on ENST00000415061 / NM_001145971.2; = p.A196T on NM_138412.4) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV52561128; called by muse, mutect2, varscan2
- RHBDL1 | c.1211G>A p.G404D (on ENST00000219551 / NM_001318733.2; = p.G339D on NM_001278720.2) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as COSV53484187; called by muse, mutect2, varscan2
- RIMS4 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs141614672; called by muse, mutect2, varscan2
- RNF122 | c.337C>T p.H113Y | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56359415; called by muse, mutect2, varscan2
- RNF166 | c.218G>T p.R73L | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57189572; called by muse, mutect2
- RPP25L | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs753365809, COSV52407593; called by muse, mutect2, varscan2
- RRAS2 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 196/599 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as rs377321245; called by muse, mutect2, varscan2
- RSPH4A | c.545A>G p.Q182R | Missense Mutation (SNP) | VAF 84/231 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.357); catalogued as rs757678261, COSV57635133; called by muse, mutect2, varscan2
- RTTN | c.226C>A p.P76T | Missense Mutation (SNP) | VAF 15/208 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV55342717; called by muse, mutect2
- RUFY3 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 117/279 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs768029243, COSV56914008; called by muse, mutect2, varscan2
- RYR3 | c.4408C>A p.L1470M | Missense Mutation (SNP) | VAF 57/174 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66791782; called by muse, mutect2, varscan2
- RYR3 | c.6941G>A p.R2314H (on ENST00000389232; = p.R2315H on NM_001036.6) | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63109677; called by muse, mutect2, varscan2
- SALL4 | c.2936G>A p.G979D | Missense Mutation (SNP) | VAF 14/197 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1320676551, COSV53852684; called by muse, mutect2
- SBF1 | c.2413G>A p.A805T | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.254); catalogued as COSV62367886; called by muse, mutect2, varscan2
- SCAF4 | c.749del p.P250Hfs*96 | Frame Shift Del (DEL) | VAF 100/625 reads (16%) | catalogued as COSV54589079; called by mutect2, pindel, varscan2
- SCCPDH | c.916A>G p.R306G | Missense Mutation (SNP) | VAF 24/590 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63618626; called by muse, mutect2
- SLC25A24 | c.570del p.K190Nfs*29 | Frame Shift Del (DEL) | VAF 33/168 reads (20%) | catalogued as rs763273320; called by mutect2, varscan2
- SLC25A33 | c.577T>C p.S193P | Missense Mutation (SNP) | VAF 85/302 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57020400; called by muse, mutect2, varscan2
- SLC26A5 | c.319G>A p.V107M | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59702227; called by muse, mutect2
- SLC4A2 | c.2159T>C p.L720P | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59657378; called by muse, mutect2
- SLC6A6 | c.1176del p.F392Lfs*31 | Frame Shift Del (DEL) | VAF 100/291 reads (34%) | catalogued as rs1390226414; called by mutect2, varscan2
- SLC7A6 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 84/252 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs144583655; called by muse, mutect2, varscan2
- SLC7A8 | c.860A>G p.Y287C | Missense Mutation (SNP) | VAF 99/287 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57554278; called by muse, mutect2, varscan2
- SMCR8 | c.2539G>A p.V847I | Missense Mutation (SNP) | VAF 20/239 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV68811021; called by muse, mutect2
- SMG1 | c.8611C>T p.R2871* | Nonsense Mutation (SNP) | VAF 33/187 reads (18%) | catalogued as COSV67171773; called by muse, mutect2, varscan2
- SNRNP200 | c.5288G>A p.R1763H | Missense Mutation (SNP) | VAF 14/424 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60490287; called by muse, mutect2
- SORCS2 | c.1714G>A p.V572M | Missense Mutation (SNP) | VAF 77/218 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1312405589, COSV61163847; called by muse, mutect2, varscan2
- SORL1 | c.5710C>T p.Q1904* | Nonsense Mutation (SNP) | VAF 135/389 reads (35%) | catalogued as rs1353361156, COSV52755288; called by muse, mutect2, varscan2
- SPAG5 | c.3382G>A p.E1128K | Missense Mutation (SNP) | VAF 18/308 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV56886371; called by muse, mutect2
- SPATA31D1 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 253/726 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.292); catalogued as rs765399068, COSV61196397; called by muse, mutect2, varscan2
- SPEF2 | c.2657del p.K886Rfs*8 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as rs750890082; called by mutect2, varscan2
- SPINDOC | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1232696994, COSV53692692; called by muse, mutect2, varscan2
- SPTB | c.3373del p.E1125Rfs*3 | Frame Shift Del (DEL) | VAF 47/159 reads (30%) | catalogued as COSV67634871; called by mutect2, pindel, varscan2
- STAM2 | c.367G>C p.D123H | Missense Mutation (SNP) | VAF 85/242 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55731708; called by muse, mutect2, varscan2
- STXBP1 | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV64813389; called by muse, mutect2, varscan2
- SUPT6H | c.3520A>G p.I1174V | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as rs1338603459, COSV58927802; called by muse, mutect2
- SV2A | c.412del p.E138Rfs*39 | Frame Shift Del (DEL) | VAF 30/86 reads (35%) | catalogued as rs1553764068; called by mutect2, pindel, varscan2
- SV2C | c.1633A>G p.T545A | Missense Mutation (SNP) | VAF 120/357 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59220985; called by muse, mutect2, varscan2
- SVIL | c.4089C>A p.N1363K (on ENST00000355867 / NM_021738.3; = p.N937K on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/253 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63443844; called by muse, varscan2
- SYN3 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 186/518 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775238041, COSV60509192; called by muse, mutect2, varscan2
- TAB2 | c.1724G>T p.R575M | Missense Mutation (SNP) | VAF 83/238 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53852831; called by muse, mutect2, varscan2
- TACC2 | c.1747C>A p.P583T | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.014); catalogued as COSV57757188; called by muse, mutect2, varscan2
- TARS1 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 73/234 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767290886, COSV54308071; called by muse, mutect2, varscan2
- TBC1D32 | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 146/425 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV51544574, COSV51551917; called by muse, mutect2, varscan2
- TBL1XR1 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 98/300 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV61790644; called by muse, mutect2, varscan2
- TCTE1 | c.562G>A p.V188M | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs763033348, COSV65255118; called by muse, mutect2, varscan2
- TMEM131L | c.2435G>A p.R812H | Missense Mutation (SNP) | VAF 112/366 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.641); catalogued as rs1254369682, COSV53645045; called by muse, mutect2, varscan2
- TMPRSS11F | c.473A>G p.Q158R | Missense Mutation (SNP) | VAF 77/220 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as COSV62466779; called by muse, mutect2, varscan2
- TNFSF12 | c.640G>A p.G214R | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV53432739; called by muse, mutect2, varscan2
- TOR1B | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 121/335 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as rs1295827436, COSV52213381; called by muse, mutect2, varscan2
- TRAP1 | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1272474481, COSV55916485; called by muse, mutect2, varscan2
- TRIM14 | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs149392923, COSV58354232; called by muse, mutect2
- TRNT1 | c.434A>C p.Q145P | Missense Mutation (SNP) | VAF 12/237 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV52408393; called by muse, mutect2
- TSPYL4 | c.182del p.G61Vfs*71 | Frame Shift Del (DEL) | VAF 13/49 reads (27%) | catalogued as COSV60310254; called by mutect2, pindel, varscan2
- TTC37 | c.3037G>A p.A1013T | Missense Mutation (SNP) | VAF 127/364 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV62454977; called by muse, varscan2
- TTN | c.74675A>G p.E24892G (on ENST00000591111; = p.E17468G on NM_003319.4) | Missense Mutation (SNP) | VAF 62/194 reads (32%) | PolyPhen possibly damaging (0.676); catalogued as COSV60098551; called by muse, mutect2, varscan2
- TYK2 | c.2719C>A p.H907N | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); catalogued as COSV53387783; called by muse, mutect2, varscan2
- UBXN1 | c.275A>G p.Q92R | Missense Mutation (SNP) | VAF 106/296 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1471191573, COSV53657439; called by muse, mutect2, varscan2
- UGGT2 | c.4170-2A>G p.X1390_splice | Splice Site (SNP) | VAF 11/177 reads (6%) | catalogued as COSV65075210; called by muse, mutect2
- UNK | c.2083G>A p.E695K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs774346420, COSV52882971, COSV52887044; called by muse, mutect2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 59/151 reads (39%) | catalogued as rs767420916; called by mutect2, varscan2
- USP16 | c.554C>A p.P185H | Missense Mutation (SNP) | VAF 105/296 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.155); catalogued as COSV57625601; called by muse, mutect2, varscan2
- USP54 | c.4250G>A p.R1417H | Missense Mutation (SNP) | VAF 38/257 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs752485943, COSV60443239; called by muse, mutect2, varscan2
- UVSSA | c.1943G>T p.G648V | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV66229292, COSV66229985; called by muse, mutect2
- VAT1L | c.502G>T p.A168S | Missense Mutation (SNP) | VAF 73/200 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100213012, COSV56820978; called by muse, mutect2, varscan2
- VNN2 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 81/280 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as rs775545409, COSV58472700; called by muse, mutect2, varscan2
- VNN3 | c.344G>A p.R115K | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.646); catalogued as COSV51591075; called by muse, mutect2, varscan2
- VPS13D | c.2103+1G>A p.X701_splice | Splice Site (SNP) | VAF 12/203 reads (6%) | catalogued as COSV62529882; called by muse, mutect2
- VPS33B | c.1574T>C p.I525T | Missense Mutation (SNP) | VAF 67/180 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.241); catalogued as COSV60980337; called by muse, mutect2
- VSIG10 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 117/309 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63653539; called by muse, mutect2, varscan2
- VWCE | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.071); catalogued as rs938469216, COSV57112781; called by muse, mutect2, varscan2
- WBP11 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 148/413 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.957); catalogued as COSV53762529; called by muse, mutect2, varscan2
- WDR27 | c.2516C>T p.A839V | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs147471495, COSV61209554; called by muse, mutect2, varscan2
- WDR90 | c.1234-2A>G p.X412_splice | Splice Site (SNP) | VAF 34/101 reads (34%) | catalogued as COSV53470587; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 40/139 reads (29%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WWC2 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 59/177 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66714046; called by muse, mutect2, varscan2
- ZDHHC20 | c.670G>A p.V224I | Missense Mutation (SNP) | VAF 66/195 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs776324785, COSV57186288; called by muse, mutect2, varscan2
- ZFYVE16 | c.3638G>A p.G1213D | Missense Mutation (SNP) | VAF 160/435 reads (37%) | SIFT tolerated (0.75); PolyPhen benign (0.012); catalogued as COSV62015907; called by muse, mutect2, varscan2
- ZNF106 | c.1444del p.S482Pfs*33 | Frame Shift Del (DEL) | VAF 145/382 reads (38%) | catalogued as rs1198467282, COSV55516091; called by mutect2, varscan2
- ZNF135 | c.1426C>T p.R476W (on ENST00000313434 / NM_001289401.2; = p.R488W on NM_003436.4) | Missense Mutation (SNP) | VAF 71/209 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs769186698, COSV57882685; called by muse, mutect2, varscan2
- ZNF236 | c.2546-2A>T p.X849_splice | Splice Site (SNP) | VAF 65/163 reads (40%) | catalogued as COSV53489316; called by muse, mutect2, varscan2
- ZNF350 | c.764C>G p.T255S | Missense Mutation (SNP) | VAF 141/352 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as rs745348588, COSV54709049; called by muse, mutect2, varscan2
- ZNF354A | c.553dup p.T185Nfs*6 | Frame Shift Ins (INS) | VAF 113/653 reads (17%) | catalogued as rs1164748265; called by pindel, varscan2
- ZNF367 | c.542C>A p.S181* | Nonsense Mutation (SNP) | VAF 113/289 reads (39%) | catalogued as COSV64546917, COSV64547059; called by muse, mutect2, varscan2
- ZNF462 | c.1864A>G p.K622E | Missense Mutation (SNP) | VAF 109/324 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV52939575; called by muse, mutect2, varscan2
- ZNF540 | c.1429C>T p.R477* | Nonsense Mutation (SNP) | VAF 39/225 reads (17%) | catalogued as rs765065304, COSV57108008; called by muse, mutect2, varscan2
- ZNF569 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 122/332 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs116491235, COSV57595804; called by muse, mutect2, varscan2
- ZNF579 | c.791del p.P264Rfs*141 | Frame Shift Del (DEL) | VAF 10/21 reads (48%) | catalogued as COSV57638182; called by mutect2, varscan2
- ZNF750 | c.1631C>T p.S544L | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV53960527; called by muse, mutect2
- ZNF846 | c.1210A>C p.N404H | Missense Mutation (SNP) | VAF 102/301 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.615); catalogued as COSV67412154; called by muse, mutect2, varscan2
- ZRANB2 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 124/331 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV54672227; called by muse, mutect2, varscan2
- ZRSR2 | c.1310G>A p.R437Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs1268612577, COSV57065060; called by muse, mutect2, varscan2
- ZZEF1 | c.2117C>T p.A706V | Missense Mutation (SNP) | VAF 84/240 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs1007857974, COSV67557809; called by muse, mutect2, varscan2
- ACAD11 | c.1608del p.K536Nfs*34 | Frame Shift Del (DEL) | VAF 125/456 reads (27%) | called by mutect2, pindel, varscan2
- AKAP5 | c.412del p.R138Gfs*8 | Frame Shift Del (DEL) | VAF 18/76 reads (24%) | called by mutect2, pindel, varscan2
- ALS2 | c.2803dup p.W935Lfs*6 | Frame Shift Ins (INS) | VAF 22/186 reads (12%) | called by mutect2, pindel, varscan2
- AP3B1 | c.2769del p.K923Nfs*4 | Frame Shift Del (DEL) | VAF 128/366 reads (35%) | called by mutect2, varscan2
- ARGFX | c.505del p.S169Lfs*3 | Frame Shift Del (DEL) | VAF 189/655 reads (29%) | called by mutect2, pindel, varscan2
- ARID1A | c.3216del p.K1072Nfs*21 | Frame Shift Del (DEL) | VAF 47/125 reads (38%) | called by mutect2, pindel, varscan2
- ARID5B | c.1490_1491dup p.E498* | Frame Shift Ins (INS) | VAF 64/163 reads (39%) | called by mutect2, pindel, varscan2
- CACNA1B | c.5923_5942del p.V1975Pfs*5 | Frame Shift Del (DEL) | VAF 14/84 reads (17%) | called by mutect2, pindel, varscan2
- CASR | c.2499del p.S834Pfs*28 (on ENST00000490131; = p.S911Pfs*28 on NM_000388.4) | Frame Shift Del (DEL) | VAF 17/62 reads (27%) | called by mutect2, pindel, varscan2
- CCAR1 | c.2416del p.S806Afs*85 | Frame Shift Del (DEL) | VAF 15/146 reads (10%) | called by mutect2, pindel, varscan2
- CDC42BPG | c.4627del p.L1543Yfs*14 | Frame Shift Del (DEL) | VAF 57/186 reads (31%) | called by mutect2, pindel, varscan2
- CDKN1B | c.275dup p.R93Afs*32 | Frame Shift Ins (INS) | VAF 19/72 reads (26%) | called by mutect2, pindel, varscan2
- CGREF1 | c.759dup p.G254Rfs*30 (on ENST00000260595; = p.G271Rfs*30 on NM_006569.6 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 32/127 reads (25%) | called by pindel, varscan2
- CNTN3 | c.136del p.I46* | Frame Shift Del (DEL) | VAF 96/298 reads (32%) | called by mutect2, pindel, varscan2
- CSRNP2 | c.1249del p.L417Wfs*14 | Frame Shift Del (DEL) | VAF 13/144 reads (9%) | called by mutect2, pindel
- CTRB1 | c.156+2T>G p.X52_splice | Splice Site (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2
- CUX1 | c.2345del p.P782Rfs*26 | Frame Shift Del (DEL) | VAF 23/82 reads (28%) | called by mutect2, pindel, varscan2
- DLG5 | c.5067del p.R1690Gfs*35 | Frame Shift Del (DEL) | VAF 44/162 reads (27%) | called by mutect2, pindel, varscan2
- DLL1 | c.845del p.G282Afs*8 | Frame Shift Del (DEL) | VAF 6/45 reads (13%) | called by mutect2, pindel, varscan2
- DNAJC7 | c.1106del p.N369Mfs*6 | Frame Shift Del (DEL) | VAF 165/568 reads (29%) | called by mutect2, pindel, varscan2
- DOK4 | c.929dup p.P311Afs*10 | Frame Shift Ins (INS) | VAF 88/283 reads (31%) | called by mutect2, pindel, varscan2
- EIF4ENIF1 | c.162dup p.Y55Ifs*2 | Frame Shift Ins (INS) | VAF 73/265 reads (28%) | called by mutect2, pindel, varscan2
- FAM13A | c.427+1del p.X143_splice | Splice Site (DEL) | VAF 8/94 reads (9%) | called by mutect2, pindel
- FOXD4L4 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 16/462 reads (3%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.14); called by muse, mutect2
- FOXM1 | c.1900_1901del p.G634Tfs*14 | Frame Shift Del (DEL) | VAF 16/45 reads (36%) | called by mutect2, pindel, varscan2
- G3BP2 | c.1225del p.T409Qfs*37 | Frame Shift Del (DEL) | VAF 221/747 reads (30%) | called by mutect2, pindel, varscan2
- GPR179 | c.590T>C p.L197P | Missense Mutation (SNP) | VAF 13/181 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HP | c.988del p.V330Cfs*5 | Frame Shift Del (DEL) | VAF 75/276 reads (27%) | called by mutect2, pindel, varscan2
- HTATSF1 | c.1503del p.E502Sfs*91 | Frame Shift Del (DEL) | VAF 14/69 reads (20%) | called by mutect2, pindel, varscan2
- ICE1 | c.842dup p.N281Kfs*13 | Frame Shift Ins (INS) | VAF 63/245 reads (26%) | called by mutect2, pindel, varscan2
- IPO9 | c.1051del p.S351Afs*10 | Frame Shift Del (DEL) | VAF 81/277 reads (29%) | called by mutect2, pindel, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 74/189 reads (39%) | called by mutect2, varscan2
- KLHL2 | c.892del p.R298Gfs*2 | Frame Shift Del (DEL) | VAF 70/208 reads (34%) | called by mutect2, pindel, varscan2
- MDC1 | c.4031del p.P1344Lfs*17 | Frame Shift Del (DEL) | VAF 176/643 reads (27%) | called by mutect2, pindel, varscan2
- MYO19 | c.9G>C p.Q3H | Missense Mutation (SNP) | VAF 20/470 reads (4%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2
- NAIF1 | c.581del p.P194Hfs*11 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, varscan2
- NR4A2 | c.881del p.N294Mfs*7 | Frame Shift Del (DEL) | VAF 48/158 reads (30%) | called by mutect2, varscan2
- NUCB2 | c.1200del p.K400Nfs*15 | Frame Shift Del (DEL) | VAF 46/138 reads (33%) | called by mutect2, varscan2
- NUP160 | c.473dup p.N158Kfs*17 | Frame Shift Ins (INS) | VAF 114/373 reads (31%) | called by mutect2, pindel, varscan2
- NUP37 | c.967del p.V323* | Frame Shift Del (DEL) | VAF 61/223 reads (27%) | called by mutect2, pindel, varscan2
- OR2S2 | c.710del p.K237Rfs*13 | Frame Shift Del (DEL) | VAF 50/189 reads (26%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1294_1298delinsT p.Q432Wfs*13 (on ENST00000521381 / NM_181523.3; = p.Q162Wfs*13 on NM_181504.4) | Frame Shift Del (DEL) | VAF 22/68 reads (32%) | called by pindel, varscan2*
- PLXNA2 | c.1393del p.H465Mfs*57 | Frame Shift Del (DEL) | VAF 18/45 reads (40%) | called by mutect2, pindel, varscan2
- PNPLA4 | c.175dup p.I59Nfs*5 | Frame Shift Ins (INS) | VAF 49/185 reads (26%) | called by mutect2, pindel, varscan2
- POMT1 | c.1461del p.Y488Ifs*69 | Frame Shift Del (DEL) | VAF 21/91 reads (23%) | called by mutect2, pindel, varscan2
- PRPSAP1 | c.749del p.N250Mfs*12 | Frame Shift Del (DEL) | VAF 46/156 reads (29%) | called by mutect2, pindel, varscan2
- PRR5-ARHGAP8 | c.1316del p.G439Afs*25 (on ENST00000352766; = p.G360Afs*25 on NM_181334.5) | Frame Shift Del (DEL) | VAF 17/53 reads (32%) | called by mutect2, pindel, varscan2
- RGL2 | c.1114del p.E372Kfs*34 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | called by mutect2, pindel, varscan2
- RNF40 | c.2159_2161del p.K720del | In Frame Del (DEL) | VAF 28/84 reads (33%) | called by pindel, varscan2
- SEC24D | c.2847del p.F949Lfs*8 | Frame Shift Del (DEL) | VAF 70/200 reads (35%) | called by mutect2, pindel, varscan2
- SLC12A4 | c.706del p.Y236Tfs*13 | Frame Shift Del (DEL) | VAF 166/485 reads (34%) | called by mutect2, pindel, varscan2
- SMTNL1 | c.1071del p.K357Nfs*96 (on ENST00000399154; = p.K394Nfs*96 on NM_001105565.2) | Frame Shift Del (DEL) | VAF 39/138 reads (28%) | called by mutect2, pindel, varscan2
- SOX4 | c.1302dup p.N435* | Frame Shift Ins (INS) | VAF 6/26 reads (23%) | called by mutect2, pindel, varscan2
- SPATS1 | c.204_205del p.S69Cfs*15 | Frame Shift Del (DEL) | VAF 119/335 reads (36%) | called by mutect2, pindel, varscan2
- SPRED1 | c.234del p.D79Tfs*42 | Frame Shift Del (DEL) | VAF 42/162 reads (26%) | called by mutect2, pindel, varscan2
- STAU2 | c.404_407del p.N135Rfs*17 (on ENST00000524300 / NM_001164380.2; = p.N103Rfs*17 on NM_014393.2) | Frame Shift Del (DEL) | VAF 49/181 reads (27%) | called by mutect2, pindel, varscan2
- STK24 | c.992del p.G331Afs*34 | Frame Shift Del (DEL) | VAF 65/206 reads (32%) | called by mutect2, pindel, varscan2
- TAF3 | c.1461del p.N488Tfs*34 | Frame Shift Del (DEL) | VAF 38/112 reads (34%) | called by mutect2, pindel, varscan2
- THUMPD3 | c.1329_1331del p.L444del | In Frame Del (DEL) | VAF 44/158 reads (28%) | called by pindel, varscan2
- TMC6 | c.1698del p.F566Lfs*14 | Frame Shift Del (DEL) | VAF 75/251 reads (30%) | called by mutect2, pindel, varscan2
- TMEM161B | c.1343del p.N448Ifs*15 | Frame Shift Del (DEL) | VAF 66/219 reads (30%) | called by mutect2, pindel, varscan2
- TMUB2 | c.383del p.G128Vfs*32 (on ENST00000538716 / NM_001353177.2; = p.G108Vfs*32 on NM_024107.3 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 38/105 reads (36%) | called by mutect2, pindel, varscan2
- ZNF563 | c.709del p.Y237Tfs*33 | Frame Shift Del (DEL) | VAF 116/367 reads (32%) | called by mutect2, pindel, varscan2
- ACBD5 | c.909C>T p.S303= (on ENST00000375888 / NM_001352568.1; = p.S294= on NM_145698.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 131/415 reads (32%) | catalogued as rs775993976, COSV65518890; called by muse, mutect2, varscan2
- ACTN3 | c.271C>T p.L91= | Silent (SNP) | VAF 69/181 reads (38%) | catalogued as COSV72207606; called by muse, mutect2, varscan2
- ADAMTS3 | c.1947T>C p.C649= | Silent (SNP) | VAF 15/294 reads (5%) | catalogued as COSV54392728; called by muse, mutect2
- AL669918.1 | c.2175G>T p.G725= | Silent (SNP) | VAF 35/97 reads (36%) | catalogued as COSV71271029; called by muse, mutect2, varscan2
- ARFGAP1 | c.78C>T p.G26= | Silent (SNP) | VAF 105/320 reads (33%) | catalogued as rs781585036, COSV62262725; called by muse, mutect2, varscan2
- ASB10 | c.816C>T p.R272= (on ENST00000420175 / NM_001142459.2; = p.R257= on NM_080871.4) | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV51996626; called by muse, mutect2, varscan2
- ASPM | c.10095C>T p.G3365= | Silent (SNP) | VAF 52/150 reads (35%) | catalogued as rs886045759, COSV54130641; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP13A4 | c.552T>C p.P184= | Silent (SNP) | VAF 8/206 reads (4%) | catalogued as COSV55069912; called by muse, mutect2
- ATP2B4 | c.879C>T p.D293= | Silent (SNP) | VAF 116/308 reads (38%) | catalogued as rs561922376, COSV58178555; called by muse, mutect2, varscan2
- BEND2 | c.1338C>T p.N446= | Silent (SNP) | VAF 247/698 reads (35%) | catalogued as COSV66215989; called by muse, mutect2, varscan2
- C14orf28 | c.789A>G p.E263= | Silent (SNP) | VAF 28/316 reads (9%) | catalogued as COSV57333425; called by muse, mutect2
- CALHM5 | c.597T>C p.C199= | Silent (SNP) | VAF 111/341 reads (33%) | catalogued as COSV62067800; called by muse, mutect2, varscan2
- CARD11 | c.3313C>T p.L1105= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as rs1236770538, COSV67799530; called by muse, mutect2, varscan2
- CARMIL3 | c.261G>A p.T87= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as rs377283873; called by muse, mutect2, varscan2
- CDADC1 | c.1029C>T p.V343= | Silent (SNP) | VAF 123/345 reads (36%) | catalogued as COSV51911756; called by muse, mutect2, varscan2
- CDH18 | c.1179C>T p.Y393= | Silent (SNP) | VAF 93/283 reads (33%) | catalogued as rs140338437; called by muse, mutect2, varscan2
- CENPK | c.739C>T p.L247= | Silent (SNP) | VAF 120/348 reads (34%) | catalogued as COSV54468377; called by muse, mutect2, varscan2
- CHERP | c.780C>T p.I260= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as rs369884233; called by muse, mutect2, varscan2
- COL12A1 | c.5466C>A p.T1822= | Silent (SNP) | VAF 41/285 reads (14%) | catalogued as COSV59396988; called by muse, mutect2, varscan2
- COL7A1 | c.3615G>A p.P1205= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as rs750065344, COSV60395918; called by muse, mutect2, varscan2
- DDX11 | c.927G>A p.Q309= | Silent (SNP) | VAF 47/296 reads (16%) | catalogued as rs765283170, COSV52504898; called by muse, mutect2, varscan2
- DDX39A | c.708T>C p.P236= | Silent (SNP) | VAF 45/110 reads (41%) | catalogued as COSV54391850; called by muse, mutect2, varscan2
- DGKH | c.651T>C p.C217= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV54933166; called by muse, mutect2, varscan2
- DLG3 | c.396C>T p.I132= | Silent (SNP) | VAF 128/304 reads (42%) | catalogued as rs767456433, COSV52080114; called by muse, mutect2, varscan2
- DNAJC10 | c.1911T>C p.F637= | Silent (SNP) | VAF 25/167 reads (15%) | catalogued as COSV51135663, COSV51138856; called by muse, mutect2, varscan2
- DOT1L | c.2169C>T p.C723= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs149636706, COSV67110088; called by muse, mutect2, varscan2
- DPY19L2 | c.390T>C p.N130= | Silent (SNP) | VAF 63/183 reads (34%) | catalogued as rs1399719821, COSV60543706; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.342G>A p.V114= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as rs1042574287, COSV56181917; called by muse, mutect2, varscan2
- F3 | c.804C>A p.I268= | Silent (SNP) | VAF 36/296 reads (12%) | catalogued as COSV61844788; called by muse, mutect2, varscan2
- FASTKD3 | c.1116C>T p.C372= | Silent (SNP) | VAF 52/171 reads (30%) | catalogued as COSV52944200; called by muse, mutect2, varscan2
- FGD2 | c.861C>A p.S287= | Silent (SNP) | VAF 47/139 reads (34%) | catalogued as rs141636165; called by muse, mutect2, varscan2
- FOCAD | c.4302C>A p.T1434= | Silent (SNP) | VAF 20/160 reads (13%) | catalogued as COSV58100104; called by muse, mutect2, varscan2
- FREM1 | c.6108C>T p.I2036= | Silent (SNP) | VAF 53/188 reads (28%) | catalogued as rs768628308, COSV66524456; called by muse, mutect2, varscan2
- GET1 | c.153G>A p.A51= | Silent (SNP) | VAF 20/296 reads (7%) | catalogued as rs142448585; called by muse, mutect2
- GPC6 | c.1233C>T p.S411= | Silent (SNP) | VAF 76/238 reads (32%) | catalogued as rs368011430, COSV65539642; called by muse, mutect2, varscan2
- GPHB5 | c.180C>T p.C60= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV58486192; called by muse, mutect2
- IDH3B | c.18A>G p.G6= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV66483343; called by muse, mutect2, varscan2
- IGSF9B | c.3441G>A p.L1147= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs762856279, COSV58068190; called by muse, mutect2, varscan2
- IPO13 | c.2760T>C p.P920= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as COSV54837286; called by muse, mutect2, varscan2
- JAK2 | c.2430T>C p.T810= | Silent (SNP) | VAF 20/118 reads (17%) | catalogued as rs1186750113, COSV67614468; called by muse, mutect2, varscan2
- KCNJ4 | c.489C>T p.I163= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs755660083, COSV57857297; called by muse, mutect2, varscan2
- KIAA0319 | c.2475T>C p.G825= | Silent (SNP) | VAF 40/99 reads (40%) | catalogued as COSV65498766; called by muse, mutect2, varscan2
- KIAA1109 | c.576C>A p.P192= | Silent (SNP) | VAF 22/240 reads (9%) | catalogued as COSV52675342; called by muse, mutect2
- KRT23 | c.1167C>T p.S389= | Silent (SNP) | VAF 79/304 reads (26%) | catalogued as COSV52927869; called by muse, mutect2, varscan2
- LAMC3 | c.3714C>T p.T1238= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as rs752191982, COSV62654393; called by muse, mutect2, varscan2
- LIG1 | c.2352C>T p.D784= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as rs1305684389, COSV54392285; called by muse, mutect2, varscan2
- LMNB2 | c.1689C>T p.V563= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as rs1366466514, COSV53113804; called by muse, mutect2, varscan2
- LPIN1 | c.1887G>A p.R629= | Silent (SNP) | VAF 8/188 reads (4%) | catalogued as COSV56766082, COSV56767433; called by muse, mutect2
- LRP1 | c.2175G>A p.T725= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as rs765435262, COSV54513153; called by muse, mutect2, varscan2
- LZTS1 | c.261C>T p.S87= | Silent (SNP) | VAF 41/138 reads (30%) | catalogued as rs1431971510, COSV56116423; called by muse, mutect2, varscan2
- MAP3K21 | c.2385G>T p.L795= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as COSV64041780; called by muse, mutect2, varscan2
- MAP7D1 | c.96C>T p.D32= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV60216597; called by muse, mutect2, varscan2
- MCM5 | c.24C>T p.G8= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs1293440847, COSV53346484; called by muse, varscan2
- MFHAS1 | c.1518C>A p.T506= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV52282702; called by muse, mutect2, varscan2
- MYBPC3 | c.363G>A p.P121= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as rs780768974, COSV57028269; ClinVar: likely benign; called by muse, mutect2, varscan2
- NBPF15 | c.1941C>T p.D647= | Silent (SNP) | VAF 225/651 reads (35%) | catalogued as rs1418573629; called by muse, mutect2, varscan2
- NDST4 | c.2019G>A p.S673= | Silent (SNP) | VAF 96/270 reads (36%) | catalogued as rs373512908, COSV52126949; called by mutect2, varscan2
- NUDT11 | c.93C>T p.D31= | Silent (SNP) | VAF 9/101 reads (9%) | catalogued as COSV65665164; called by muse, mutect2
- OR2A5 | c.570T>C p.A190= | Silent (SNP) | VAF 68/219 reads (31%) | catalogued as COSV68738792; called by muse, mutect2, varscan2
- ORC4 | c.942A>G p.K314= | Silent (SNP) | VAF 131/382 reads (34%) | catalogued as COSV51574244; called by muse, mutect2, varscan2
- PCDHA4 | c.1851C>T p.G617= | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as rs370669259; called by muse, mutect2, varscan2
- PCDHB6 | c.2131C>T p.L711= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as COSV50699846; called by muse, mutect2, varscan2
- PDCD6 | c.360A>G p.S120= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV53778004; called by muse, mutect2, varscan2
- PDE3B | c.747C>T p.S249= | Silent (SNP) | VAF 17/28 reads (61%) | catalogued as rs762406309, COSV56384418; called by muse, mutect2, varscan2
- PDE5A | c.873C>T p.N291= | Silent (SNP) | VAF 151/412 reads (37%) | catalogued as rs199732889, COSV53348702; called by muse, mutect2, varscan2
- PHACTR2 | c.1347C>T p.I449= | Silent (SNP) | VAF 16/376 reads (4%) | catalogued as COSV59854954; called by muse, mutect2
- PHF2 | c.1740T>G p.V580= | Silent (SNP) | VAF 34/442 reads (8%) | catalogued as COSV63681233; called by muse, mutect2
- PHKA2 | c.2397C>T p.H799= | Silent (SNP) | VAF 39/137 reads (28%) | catalogued as rs181179616, COSV66054252; called by muse, mutect2, varscan2
- PHOX2A | c.321C>T p.R107= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as COSV53356017; called by muse, mutect2, varscan2
- PIGA | c.609G>A p.V203= | Silent (SNP) | VAF 140/375 reads (37%) | catalogued as COSV61237729; called by muse, mutect2, varscan2
- PLEKHG4 | c.1110C>T p.V370= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs779926696, COSV64612908; called by muse, mutect2, varscan2
- PRSS38 | c.228C>T p.S76= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs540885637, COSV64539935; called by muse, mutect2, varscan2
- PTPRS | c.5439C>T p.Y1813= | Silent (SNP) | VAF 28/252 reads (11%) | catalogued as COSV53621537; called by muse, mutect2, varscan2
- RIPK3 | c.733C>T p.L245= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as COSV53475701; called by muse, mutect2, varscan2
- SAP130 | c.2241G>A p.A747= | Silent (SNP) | VAF 202/533 reads (38%) | catalogued as rs199719276; called by muse, mutect2, varscan2
- SIGLEC14 | c.766C>T p.L256= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV55780067; called by muse, mutect2, varscan2
- SLC16A10 | c.885G>A p.V295= | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as COSV64354361; called by muse, mutect2, varscan2
- SLC25A28 | c.573G>T p.A191= | Silent (SNP) | VAF 58/192 reads (30%) | catalogued as COSV65125428; called by muse, mutect2, varscan2
- SMARCA4 | c.2322C>T p.N774= | Silent (SNP) | VAF 71/193 reads (37%) | catalogued as rs528157497, COSV60795963; ClinVar: likely benign; called by muse, mutect2, varscan2
- SNAI2 | c.714A>G p.V238= | Silent (SNP) | VAF 111/322 reads (34%) | catalogued as COSV50079203; called by muse, mutect2, varscan2
- SNIP1 | c.720G>A p.R240= | Silent (SNP) | VAF 56/164 reads (34%) | catalogued as COSV56166732; called by muse, mutect2, varscan2
- SORCS1 | c.3351C>T p.F1117= | Silent (SNP) | VAF 17/245 reads (7%) | catalogued as rs767281051, COSV53863535; called by muse, mutect2
- SQOR | c.753G>A p.Q251= | Silent (SNP) | VAF 54/143 reads (38%) | catalogued as COSV52942042; called by muse, mutect2, varscan2
- SRCAP | c.3294G>A p.R1098= | Silent (SNP) | VAF 22/210 reads (10%) | catalogued as COSV99349346; called by muse, mutect2
- STEAP3 | c.327G>A p.K109= | Silent (SNP) | VAF 61/174 reads (35%) | catalogued as COSV61529228; called by muse, mutect2, varscan2
- SYNJ2 | c.612C>T p.C204= | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as COSV62897722; called by muse, mutect2
- TANGO6 | c.1914G>A p.E638= | Silent (SNP) | VAF 18/173 reads (10%) | catalogued as COSV55766154; called by muse, mutect2, varscan2
- TIAM2 | c.4725C>A p.P1575= (on ENST00000529824; = p.P1546= on NM_012454.3) | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as COSV51637759, COSV51640980; called by muse, mutect2, varscan2
- TLN1 | c.6246C>T p.N2082= | Silent (SNP) | VAF 149/438 reads (34%) | catalogued as rs11541906, COSV59207920; called by muse, mutect2, varscan2
- TMEM236 | c.594G>A p.S198= | Silent (SNP) | VAF 66/167 reads (40%) | catalogued as rs1461656083; called by muse, mutect2, varscan2
- TPBG | c.958C>A p.R320= | Silent (SNP) | VAF 27/127 reads (21%) | catalogued as COSV63882652; called by muse, mutect2, varscan2
- TPGS2 | c.64C>T p.L22= | Silent (SNP) | VAF 42/126 reads (33%) | catalogued as COSV54454879, COSV99693604; called by muse, mutect2, varscan2
- TRIM41 | c.1287G>A p.A429= | Silent (SNP) | VAF 63/165 reads (38%) | catalogued as rs368524571; called by muse, mutect2, varscan2
- TRPC3 | c.831G>A p.R277= (on ENST00000379645 / NM_001366479.2; = p.R204= on NM_003305.2) | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV53376221; called by muse, mutect2, varscan2
- TRPC6 | c.1704G>A p.T568= | Silent (SNP) | VAF 66/247 reads (27%) | catalogued as rs746304987, COSV60255459; called by muse, mutect2, varscan2
- TRPS1 | c.702C>T p.N234= (on ENST00000220888 / NM_001330599.2; = p.N247= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 70/216 reads (32%) | catalogued as rs577432775, COSV104378173, COSV55242514; called by muse, mutect2, varscan2
- TRPV1 | c.918G>A p.V306= | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as COSV51516515, COSV51519088; called by muse, mutect2, varscan2
- USP18 | c.717G>A p.G239= | Silent (SNP) | VAF 76/219 reads (35%) | catalogued as COSV53173586; called by muse, mutect2, varscan2
- VPS72 | c.846G>A p.R282= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as COSV54860867; called by muse, mutect2, varscan2
- WDR7 | c.120C>T p.D40= | Silent (SNP) | VAF 49/162 reads (30%) | catalogued as rs372416512; called by muse, mutect2, varscan2
- WNK1 | c.3561A>G p.K1187= (on ENST00000315939 / NM_018979.4; = p.K940= on NM_014823.3) | Silent (SNP) | VAF 132/396 reads (33%) | catalogued as COSV60034683; called by muse, mutect2, varscan2
- XPO7 | c.1506A>G p.A502= | Silent (SNP) | VAF 84/278 reads (30%) | catalogued as rs761198116, COSV53015388; called by muse, varscan2
- ZNF181 | c.489C>A p.T163= | Silent (SNP) | VAF 5/102 reads (5%) | catalogued as COSV67626795; called by muse, mutect2
- ZSCAN25 | c.1110C>T p.H370= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as rs367863945; called by muse, mutect2, varscan2
- DEPDC5 | c.*838G>A | 3'UTR (SNP) | VAF 15/36 reads (42%) | catalogued as rs370366925; called by muse, mutect2, varscan2
- GAD2 | c.-2C>T | 5'UTR (SNP) | VAF 41/101 reads (41%) | catalogued as rs1171276341, COSV52152463; called by muse, mutect2, varscan2
- HMGB1P1 | n.573G>T | RNA (SNP) | VAF 40/339 reads (12%) | called by muse, mutect2, varscan2
- INTS7 | c.-1C>T | 5'UTR (SNP) | VAF 55/147 reads (37%) | catalogued as COSV100877148; called by muse, mutect2, varscan2
- N4BP2L2 | chr13:32442802 G>T | 3'Flank (SNP) | VAF 12/33 reads (36%) | catalogued as COSV62633203; called by muse, mutect2, varscan2
- OR52A4P | chr11:5120791 del A | 3'Flank (DEL) | VAF 40/73 reads (55%) | catalogued as rs769032953; called by mutect2, varscan2
- SORBS2 | c.685-7554T>C | Intron (SNP) | VAF 92/315 reads (29%) | catalogued as COSV53001820; called by muse, mutect2, varscan2
- SSPOP | n.13633G>A | RNA (SNP) | VAF 29/74 reads (39%) | catalogued as COSV65130754; called by muse, mutect2, varscan2
